Somatic mutation profile of tumor specimen C3N-01878-01 (aliquot CPT0117560006) from CPTAC case C3N-01878, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G2; Age at diagnosis: 59.3 years (21,655 days).
Specimen C3N-01878-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d5b2e4b-4aa9-4e2b-a2ee-69c3cb611ea6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01878-31 (Blood Derived Normal), aliquot CPT0117620002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c3e5b99-66c5-476a-9107-c2646f3c4ea2

The open-access MAF lists 1,069 somatic variants for this specimen: 713 protein-altering or splice-affecting, 191 silent, 165 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 443, Silent 191, Frame Shift Del 165, Intron 91, 3'UTR 34, Nonsense Mutation 31, Frame Shift Ins 30, Splice Site 23, RNA 21, Splice Region 12, 5'UTR 8, 3'Flank 7.

Variants (750 of 1,069; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BARD1 | c.623del p.K208Rfs*4 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | catalogued as rs587780033; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- F8 | c.4379del p.N1460Ifs*5 | Frame Shift Del (DEL) | VAF 38/116 reads (33%) | catalogued as rs387906455, CD910498; ClinVar: pathogenic; called by mutect2, varscan2
- FLNB | c.1592del p.G531Dfs*42 | Frame Shift Del (DEL) | VAF 43/148 reads (29%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, varscan2
- KIF7 | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 65/234 reads (28%) | catalogued as rs387907044, CM113619, COSV67998606; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.10162C>T p.Q3388* | Nonsense Mutation (SNP) | VAF 40/154 reads (26%) | catalogued as rs1555048203; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 123/292 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRIT1 | c.1710del p.K570Nfs*7 | Frame Shift Del (DEL) | VAF 34/127 reads (27%) | catalogued as rs1563244807, CD992746; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 33/128 reads (26%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MYO15A | c.1185del p.E396Rfs*48 | Frame Shift Del (DEL) | VAF 94/318 reads (30%) | catalogued as rs772536599; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- NEK1 | c.1908del p.V637Cfs*34 | Frame Shift Del (DEL) | VAF 34/114 reads (30%) | catalogued as rs775849720; ClinVar: likely pathogenic; called by mutect2, varscan2
- NFE2L2 | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 78/331 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960014, COSV67960167, COSV67960618; called by muse, mutect2, varscan2
- PIK3CA | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs886042002, CM162636, COSV55873442, COSV55926654, COSV55949642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.2702G>T p.C901F | Missense Mutation (SNP) | VAF 26/73 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55881149; called by muse, mutect2, varscan2
- ZNF469 | c.10248dup p.R3417Afs*58 (on ENST00000437464; = p.R3445Afs*58 on NM_001367624.2) | Frame Shift Ins (INS) | VAF 14/85 reads (16%) | catalogued as rs764470052; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AADACL4 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as COSV66106431; called by muse, mutect2, varscan2
- ABCA9 | c.337del p.S113Afs*7 | Frame Shift Del (DEL) | VAF 25/93 reads (27%) | catalogued as rs367985525; called by mutect2, pindel
- ABCB6 | c.953del p.G318Vfs*9 | Frame Shift Del (DEL) | VAF 43/166 reads (26%) | catalogued as rs777439793; called by mutect2, pindel, varscan2
- ABHD17A | c.638C>T p.P213L (on ENST00000292577 / NM_001130111.2; = p.P264L on NM_031213.4) | Missense Mutation (SNP) | VAF 88/389 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV51749713, COSV99171198; called by muse, mutect2, varscan2
- AC006059.2 | c.1402C>T p.R468* | Nonsense Mutation (SNP) | VAF 79/256 reads (31%) | catalogued as rs564647857, COSV100045189; called by muse, mutect2, varscan2
- AC099489.1 | c.4369C>A p.R1457S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.99); PolyPhen benign (0.106); catalogued as rs528422545; called by muse, mutect2, varscan2
- ACSF3 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 62/264 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as rs746501634, COSV58080753; called by muse, mutect2, varscan2
- ADAMTS13 | c.4205G>A p.R1402Q | Missense Mutation (SNP) | VAF 108/376 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.078); catalogued as rs782297535, COSV52471284; called by muse, mutect2, varscan2
- ADAMTS20 | c.1471C>T p.L491F | Missense Mutation (SNP) | VAF 45/208 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.654); catalogued as COSV67130029; called by muse, mutect2, varscan2
- ADCY7 | c.1121G>A p.G374D | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54266189; called by muse, mutect2, varscan2
- ADGRA2 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 63/229 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771754787, COSV100177915, COSV59447086; called by muse, mutect2, varscan2
- ADORA1 | c.245T>C p.M82T | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs940733712; called by muse, mutect2, varscan2
- AIMP2 | c.413T>C p.L138P | Missense Mutation (SNP) | VAF 79/285 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs765096358; called by muse, mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 64/228 reads (28%) | catalogued as COSV62339755; called by mutect2, varscan2
- ANKRD2 | c.1069G>A p.V357M | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as rs138862885; called by muse, mutect2, varscan2
- ANTXR2 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1320164744, COSV56315391; called by muse, mutect2, varscan2
- APOBEC3B | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 151/898 reads (17%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.621); catalogued as rs767250819; called by muse, mutect2, varscan2
- ARAP1 | c.3629G>A p.R1210Q (on ENST00000393609 / NM_001040118.2; = p.R965Q on NM_015242.4) | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs773658481; called by muse, mutect2, varscan2
- ARID1A | c.2402del p.G801Vfs*32 | Frame Shift Del (DEL) | VAF 22/103 reads (21%) | catalogued as COSV61388445; called by mutect2, pindel, varscan2
- ARID1B | c.521del p.P174Rfs*6 | Frame Shift Del (DEL) | VAF 13/77 reads (17%) | catalogued as rs1562376341; called by mutect2, pindel, varscan2
- ARPIN | c.164G>A p.R55K | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs759994780; called by muse, mutect2, varscan2
- ARRDC2 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 83/314 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as rs780507396; called by muse, mutect2, varscan2
- ASPG | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 63/312 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs763586318; called by muse, mutect2, varscan2
- ATF5 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs1159470845; called by muse, mutect2
- ATP7A | c.2792A>G p.Q931R | Missense Mutation (SNP) | VAF 71/261 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1372577709; called by muse, mutect2, varscan2
- BAZ2A | c.2072G>A p.R691H | Missense Mutation (SNP) | VAF 63/244 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs771601416, COSV51635445, COSV51639867; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 56/302 reads (19%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BRD1 | c.824C>A p.P275H | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs17854474; called by muse, mutect2, varscan2
- BRD4 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs771383580, COSV54591314; called by muse, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 20/54 reads (37%) | catalogued as rs749043197; called by mutect2, varscan2
- BRINP2 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773810112, COSV64177191; called by muse, mutect2, varscan2
- BTBD8 | c.2824C>T p.P942S (on ENST00000636805 / NM_001376131.1; = p.P429S on NM_015237.4) | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.053); catalogued as rs1394681313; called by muse, mutect2, varscan2
- C2orf16 | c.72dup p.I25Yfs*30 | Frame Shift Ins (INS) | VAF 52/214 reads (24%) | catalogued as rs766219691; called by mutect2, varscan2
- CA4 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 161/531 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs777463944, COSV56281014; called by muse, mutect2, varscan2
- CACNA2D4 | c.833del p.N278Tfs*15 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | catalogued as COSV54961430; called by mutect2, pindel, varscan2
- CACTIN | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 96/341 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs1568290119, COSV50269351; called by muse, mutect2, varscan2
- CASP5 | c.533dup p.N178Kfs*3 | Frame Shift Ins (INS) | VAF 28/148 reads (19%) | catalogued as rs765105588; called by mutect2, varscan2
- CBX5 | c.317del p.K106Rfs*31 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | catalogued as rs780649799; called by mutect2, varscan2
- CCDC130 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.3); catalogued as rs1460264931; called by muse, mutect2, varscan2
- CCDC168 | c.21051del p.F7017Lfs*25 | Frame Shift Del (DEL) | VAF 23/40 reads (58%) | catalogued as rs397851855; called by mutect2, varscan2
- CCDC33 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as rs182048903; called by muse, mutect2
- CCNB3 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.301); catalogued as rs782775027, COSV52078760; called by muse, mutect2, varscan2
- CCNI2 | c.133del p.E45Rfs*138 | Frame Shift Del (DEL) | VAF 66/274 reads (24%) | catalogued as rs1451822015; called by mutect2, varscan2
- CENPB | c.1312dup p.E438Gfs*16 | Frame Shift Ins (INS) | VAF 14/50 reads (28%) | catalogued as rs748211874; called by mutect2, varscan2
- CFAP46 | c.5755G>A p.V1919I | Missense Mutation (SNP) | VAF 75/273 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1384910406, COSV54156694; called by muse, mutect2, varscan2
- CFAP70 | c.2690T>C p.M897T | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as rs1477622152; called by muse, mutect2, varscan2
- CHCHD6 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99337271; called by muse, mutect2, varscan2
- CHMP7 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.076); catalogued as rs1224558994; called by muse, mutect2, varscan2
- CLGN | c.1522del p.T508Pfs*12 | Frame Shift Del (DEL) | VAF 30/131 reads (23%) | catalogued as rs1217577246; called by mutect2, pindel, varscan2
- COL17A1 | c.1170del p.E391Kfs*12 | Frame Shift Del (DEL) | VAF 80/330 reads (24%) | catalogued as rs769586532; called by mutect2, pindel, varscan2
- COL22A1 | c.2174del p.P725Lfs*90 | Frame Shift Del (DEL) | VAF 51/243 reads (21%) | catalogued as rs1301137828; called by mutect2, pindel, varscan2
- CPLX3 | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 13/245 reads (5%) | catalogued as rs1386054056; called by muse, mutect2
- CPSF6 | c.985G>A p.G329S | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.89); PolyPhen benign (0.087); catalogued as rs777746807; called by muse, mutect2, varscan2
- CRIM1 | c.1309G>A p.V437I | Missense Mutation (SNP) | VAF 104/394 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs771535773, COSV54860184; called by muse, mutect2, varscan2
- CSNK1D | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 88/285 reads (31%) | catalogued as COSV53923901; called by muse, mutect2, varscan2
- CSNK2A3 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 109/373 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs755106332; called by muse, mutect2, varscan2
- CSPG4 | c.4676G>A p.R1559H | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs199703779; called by muse, mutect2, varscan2
- CXCR2 | c.236G>A p.G79D | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.158); catalogued as COSV59281867; called by muse, mutect2, varscan2
- CYLD | c.2179G>A p.V727I | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs762650238, COSV61094909; called by muse, mutect2
- CYP2E1 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 66/241 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1324031177, COSV53313649, COSV53315767; called by muse, mutect2, varscan2
- DBF4B | c.1670G>T p.R557L | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100154740; called by muse, mutect2, varscan2
- DCAF12L2 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as COSV100758500, COSV63582989; called by muse, mutect2, varscan2
- DDN | c.1586del p.G529Afs*28 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | catalogued as COSV100305547; called by mutect2, pindel
- DDX60L | c.3503dup p.N1168Kfs*6 | Frame Shift Ins (INS) | VAF 17/56 reads (30%) | catalogued as rs772416332; called by mutect2, varscan2
- DHX30 | c.2034G>A p.W678* (on ENST00000445061 / NM_138615.3; = p.W639* on NM_014966.3) | Nonsense Mutation (SNP) | VAF 35/129 reads (27%) | catalogued as COSV99275415; called by muse, mutect2, varscan2
- DISP1 | c.1479_1480del p.H493Qfs*80 | Frame Shift Del (DEL) | VAF 83/348 reads (24%) | catalogued as rs1236378836; called by pindel, varscan2
- DLG5 | c.2852T>C p.M951T | Missense Mutation (SNP) | VAF 105/351 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs752939677; called by muse, mutect2, varscan2
- DLGAP3 | c.254dup p.S86* | Frame Shift Ins (INS) | VAF 32/114 reads (28%) | catalogued as rs762874947; called by mutect2, varscan2
- DMRTB1 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 69/229 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs949268865; called by muse, mutect2, varscan2
- DMXL2 | c.2512G>A p.A838T | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.454); catalogued as rs199866251; called by muse, mutect2, varscan2
- DNAH17 | c.106A>G p.N36D | Missense Mutation (SNP) | VAF 67/288 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.089); catalogued as rs868743383, COSV101104141; called by muse, mutect2, varscan2
- DNAI4 | c.763A>G p.M255V | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as rs200179462; called by muse, mutect2, varscan2
- DNAJC18 | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 7/93 reads (8%) | catalogued as rs1423917155; called by muse, mutect2
- DOHH | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 106/389 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs537473356, COSV51744238; called by muse, mutect2, varscan2
- DSE | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.964); catalogued as rs150311697; called by muse, mutect2, varscan2
- DST | c.12059A>G p.H4020R (on ENST00000361203 / NM_001374722.1; = p.H1608R on NM_015548.5) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as rs758393601; called by muse, mutect2, varscan2
- EBLN1 | c.230del p.P77Qfs*3 | Frame Shift Del (DEL) | VAF 26/129 reads (20%) | catalogued as COSV69370220; called by mutect2, pindel
- EDEM1 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99849192; called by muse, mutect2, varscan2
- EHBP1L1 | c.3907G>A p.A1303T | Missense Mutation (SNP) | VAF 230/736 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as rs1377769142; called by muse, mutect2, varscan2
- EHMT1 | c.425C>T p.T142I | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as rs1164812479; called by muse, mutect2, varscan2
- EHMT1 | c.2509G>A p.A837T | Missense Mutation (SNP) | VAF 94/352 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.112); catalogued as rs398124406, COSV71778143; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPHA8 | c.2716G>A p.A906T | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as rs142726625; called by muse, mutect2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 30/53 reads (57%) | catalogued as rs768793415; called by mutect2, varscan2
- ERN2 | c.2011C>T p.R671C | Missense Mutation (SNP) | VAF 66/282 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1454907562; called by muse, varscan2
- EXOC3L1 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs781175340; called by muse, mutect2, varscan2
- FAM114A2 | c.436_438del p.S146del | In Frame Del (DEL) | VAF 33/123 reads (27%) | catalogued as rs1298245475; called by pindel, varscan2
- FAM13B | c.1603C>T p.H535Y | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV50366671; called by muse, mutect2, varscan2
- FAM189A2 | c.1054G>T p.D352Y | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99975199; called by muse, mutect2, varscan2
- FAM47C | c.2059G>A p.V687I | Missense Mutation (SNP) | VAF 109/452 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as rs1215954460, COSV63726680; called by muse, varscan2
- FAM86B1 | c.292G>T p.G98C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs553784650; called by mutect2, varscan2
- FANCM | c.4005del p.V1336Lfs*2 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs746983128; called by mutect2, varscan2
- FASN | c.4705G>A p.A1569T | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.16); catalogued as rs914258123; called by muse, mutect2, varscan2
- FBN1 | c.7516G>A p.G2506S | Missense Mutation (SNP) | VAF 86/349 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.04); catalogued as rs756295016; ClinVar: likely benign / benign / uncertain significance; called by muse, mutect2, varscan2
- FBXL7 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 96/366 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV61646201; called by muse, mutect2, varscan2
- FGD5 | c.3523G>A p.A1175T | Missense Mutation (SNP) | VAF 78/260 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.782); catalogued as rs778123953, COSV99549236; called by muse, mutect2, varscan2
- FKBP8 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs1466166801; called by muse, mutect2, varscan2
- FLG2 | c.7108del p.S2370Afs*32 | Frame Shift Del (DEL) | VAF 45/181 reads (25%) | catalogued as rs1457697914; called by mutect2, pindel, varscan2
- FLNB | c.2995C>T p.R999W | Missense Mutation (SNP) | VAF 103/408 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs746184200, COSV55891738; called by muse, mutect2, varscan2
- FMN1 | c.2645C>A p.P882H (on ENST00000616417 / NM_001277313.2; = p.P659H on NM_001103184.4) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); catalogued as rs963451759; called by muse, mutect2
- FOXG1 | c.221C>A p.P74Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs796052452, COSV57398153; ClinVar: likely benign; called by muse, varscan2
- FRAT1 | c.581C>T p.T194I | Missense Mutation (SNP) | VAF 136/518 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs1215714803; called by muse, mutect2, varscan2
- FRMPD3 | c.2530C>T p.R844C | Missense Mutation (SNP) | VAF 71/243 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs542524568; called by muse, mutect2, varscan2
- FXR1 | c.171del p.E58Kfs*8 | Frame Shift Del (DEL) | VAF 18/69 reads (26%) | catalogued as rs1559986435; called by mutect2, pindel, varscan2
- FZR1 | c.1124dup p.G376Rfs*4 | Frame Shift Ins (INS) | VAF 19/122 reads (16%) | catalogued as rs1350973455; called by mutect2, pindel, varscan2
- GABRA2 | c.1118A>G p.N373S | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.046); catalogued as rs1175283561, COSV62911822; called by muse, mutect2, varscan2
- GABRB1 | c.180del p.V61Sfs*12 | Frame Shift Del (DEL) | VAF 5/47 reads (11%) | catalogued as COSV54981989; called by mutect2, pindel, varscan2
- GANAB | c.2050C>T p.R684* | Nonsense Mutation (SNP) | VAF 91/311 reads (29%) | catalogued as COSV100647734; called by muse, mutect2, varscan2
- GHSR | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 82/297 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV53839566; called by muse, mutect2, varscan2
- GLI2 | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 28/100 reads (28%) | catalogued as COSV58051605; called by muse, mutect2, varscan2
- GLIS1 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1557469875, COSV56550038; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 26/74 reads (35%) | catalogued as rs370114090; called by mutect2, varscan2
- GPIHBP1 | c.277A>G p.I93V | Missense Mutation (SNP) | VAF 114/432 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.057); catalogued as rs1217204653; called by muse, mutect2, varscan2
- GPR158 | c.1690del p.T564Hfs*18 | Frame Shift Del (DEL) | VAF 57/242 reads (24%) | catalogued as COSV66272641; called by mutect2, pindel, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs754199513; called by mutect2, varscan2
- GTDC1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53993103; called by muse, mutect2, varscan2
- H2BW1 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 77/309 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as rs200090293, COSV54220759; called by muse, mutect2, varscan2
- HAPLN4 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.34); catalogued as rs1316087431; called by muse, mutect2, varscan2
- HECTD2 | c.1654G>A p.V552M | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs754119874; called by muse, mutect2, varscan2
- HELZ2 | c.2156G>A p.R719H (on ENST00000467148 / NM_001037335.2; = p.R150H on NM_033405.3) | Missense Mutation (SNP) | VAF 19/525 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100915416; called by muse, mutect2
- HERC2 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.539); catalogued as rs779353738, COSV55333983, COSV99875177; called by muse, mutect2, varscan2
- HMX1 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 88/321 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101272896; called by muse, mutect2, varscan2
- HS3ST4 | c.732C>T p.Y244= | Splice Region (SNP) | VAF 22/62 reads (35%) | catalogued as rs1267004633; called by muse, varscan2
- HSF5 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs199938494; called by muse, mutect2
- HTR1A | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 185/682 reads (27%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as COSV100108824; called by muse, mutect2, varscan2
- HTT | c.4992G>A p.A1664= | Splice Region (SNP) | VAF 29/128 reads (23%) | catalogued as rs749602044, COSV100750938; called by muse, mutect2, varscan2
- HUWE1 | c.9611G>A p.R3204H | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53337879; called by muse, mutect2, varscan2
- IFITM1 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.473); catalogued as rs371803538; called by muse, mutect2
- IKBKE | c.231C>T p.G77= | Splice Region (SNP) | VAF 34/96 reads (35%) | catalogued as rs781884386, COSV65626538; called by muse, mutect2, varscan2
- IL1RAPL1 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 90/340 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs1365228431, COSV100149498, COSV56245289; called by muse, mutect2, varscan2
- IL6R | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs112354168; called by muse, mutect2, varscan2
- INO80 | c.3841C>T p.R1281W | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1482292423, COSV62736759; called by muse, mutect2, varscan2
- INPP5E | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 114/420 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779363781, COSV65496093; called by muse, mutect2, varscan2
- INSM2 | c.1605dup p.S536* | Frame Shift Ins (INS) | VAF 52/212 reads (25%) | catalogued as rs756928018; called by mutect2, varscan2
- IQSEC2 | c.1339G>A p.V447I (on ENST00000642864 / NM_001111125.3; = p.V242I on NM_015075.2) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs1556864546, COSV64724935; ClinVar: likely benign; called by muse, mutect2, varscan2
- ITGA11 | c.2842C>T p.R948C | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.436); catalogued as rs754430765; called by muse, mutect2, varscan2
- ITGA5 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104394745; called by muse, mutect2, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 32/77 reads (42%) | catalogued as rs755650243; called by mutect2, pindel, varscan2
- KCNIP2 | c.209G>A p.R70H (on ENST00000356640 / NM_173191.3; = p.R85H on NM_014591.5) | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.038); catalogued as rs929916944; called by muse, mutect2, varscan2
- KCNJ14 | c.281_283del p.S94del | In Frame Del (DEL) | VAF 71/288 reads (25%) | catalogued as rs774240298; called by mutect2, pindel, varscan2
- KCTD15 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs199530630; called by muse, mutect2, varscan2
- KDM4C | c.2492G>A p.R831H | Missense Mutation (SNP) | VAF 64/273 reads (23%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.72); catalogued as rs776663828; called by muse, mutect2, varscan2
- KDM5C | c.3173G>A p.G1058D | Missense Mutation (SNP) | VAF 79/282 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1556835976; called by muse, mutect2, varscan2
- KDR | c.2954A>G p.D985G | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.987); catalogued as rs931465705; called by muse, mutect2, varscan2
- KHNYN | c.-18+5G>A | Splice Region (SNP) | VAF 33/152 reads (22%) | catalogued as rs1450721437; called by muse, mutect2, varscan2
- KIAA2026 | c.2187del p.A730Qfs*26 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | catalogued as rs749990720; called by mutect2, varscan2
- KIF5C | c.2609G>A p.R870H | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68483397; called by muse, mutect2, varscan2
- KIFC1 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1474616986; called by muse, mutect2, varscan2
- KLHDC1 | c.442A>G p.S148G | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as rs1566609415; called by muse, mutect2, varscan2
- KLK8 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 66/243 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs979950210; called by muse, mutect2, varscan2
- KPRP | c.969del p.K324Sfs*47 | Frame Shift Del (DEL) | VAF 58/188 reads (31%) | catalogued as COSV64221091, COSV64221342; called by mutect2, pindel, varscan2
- KSR1 | c.872del p.P291Hfs*36 (on ENST00000644974 / NM_001367810.1; = p.P154Hfs*36 on NM_014238.2) | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | catalogued as rs750491454; called by mutect2, varscan2
- LATS1 | c.2770C>T p.R924* | Nonsense Mutation (SNP) | VAF 24/79 reads (30%) | catalogued as rs145871963; called by muse, mutect2, varscan2
- LBP | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 61/236 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs756114008; called by muse, mutect2, varscan2
- LBR | c.851C>T p.T284M | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.028); catalogued as rs371750924; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LENG9 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV56618721; called by muse, mutect2
- LIPI | c.650G>A p.S217N | Missense Mutation (SNP) | VAF 84/327 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV60713275; called by muse, mutect2, varscan2
- LMTK3 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs1266153335; called by muse, mutect2, varscan2
- LRP10 | c.1975C>T p.R659* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as rs1335310645; called by muse, mutect2, varscan2
- MAOA | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 91/357 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs779299641; called by muse, mutect2, varscan2
- MAP3K13 | c.2480T>C p.V827A | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.978); catalogued as rs186776808; called by muse, mutect2, varscan2
- MAP3K4 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140581305; called by muse, mutect2, varscan2
- MAP7D1 | c.889G>A p.V297M | Missense Mutation (SNP) | VAF 86/298 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100294193; called by muse, mutect2, varscan2
- MAPK9 | c.1250C>T p.T417M | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.63); catalogued as rs149127216; called by muse, mutect2, varscan2
- MATN2 | c.2020G>A p.V674M | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs756209937; called by muse, mutect2, varscan2
- MCM9 | c.2464del p.R822Gfs*2 | Frame Shift Del (DEL) | VAF 27/108 reads (25%) | catalogued as rs1298669721; called by mutect2, pindel, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 20/138 reads (14%) | catalogued as rs762115034; called by mutect2, pindel, varscan2
- MEGF8 | c.5742del p.C1915Afs*128 (on ENST00000251268 / NM_001271938.2; = p.C1848Afs*128 on NM_001410.3) | Frame Shift Del (DEL) | VAF 43/189 reads (23%) | catalogued as COSV52075474; called by mutect2, pindel, varscan2
- MEST | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); catalogued as rs1186362030; called by muse, mutect2, varscan2
- METTL25 | c.479A>G p.Q160R | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.42); catalogued as rs761670272; called by muse, varscan2
- MFGE8 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 82/327 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1354791423; called by muse, mutect2, varscan2
- MFSD8 | c.558del p.Q187Rfs*12 | Frame Shift Del (DEL) | VAF 24/95 reads (25%) | catalogued as rs1350716726; called by mutect2, pindel, varscan2
- MLXIP | c.1460C>T p.T487M | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1235951859; called by muse, mutect2
- MRAS | c.248G>T p.R83L | Missense Mutation (SNP) | VAF 70/217 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56673673, COSV56673724; called by muse, mutect2, varscan2
- MROH2A | c.4211G>A p.R1404Q | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as rs978988264; called by muse, mutect2
- MROH7 | c.3356G>A p.R1119H | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs370697369; called by muse, mutect2, varscan2
- MRPS22 | c.984+15del | Splice Region (DEL) | VAF 53/210 reads (25%) | catalogued as rs372892045; ClinVar: uncertain significance / likely benign; called by mutect2, varscan2
- MUC17 | c.5231C>A p.P1744H | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100073310; called by muse, mutect2, varscan2
- MXRA5 | c.6440G>A p.R2147H | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54229047, COSV54244657; called by muse, mutect2, varscan2
- MYBPC3 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 72/262 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); catalogued as rs549239819; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO15A | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 53/202 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs981927941, COSV52756314; called by muse, mutect2, varscan2
- MYO15A | c.3610-8T>A | Splice Region (SNP) | VAF 100/366 reads (27%) | catalogued as rs765041022, COSV52751650; called by mutect2, varscan2
- MYO7A | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1434564086; called by muse, mutect2, varscan2
- MYRF | c.789del p.S264Afs*8 (on ENST00000278836 / NM_001127392.3; = p.S255Afs*8 on NM_013279.4) | Frame Shift Del (DEL) | VAF 27/86 reads (31%) | catalogued as rs769274302, COSV53895135; called by mutect2, varscan2
- NAALADL1 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375401003; called by muse, mutect2, varscan2
- NANOS3 | c.298C>T p.R100C (on ENST00000397555; = p.R119C on NM_001098622.2) | Missense Mutation (SNP) | VAF 67/267 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV59249268; called by muse, mutect2, varscan2
- NARS2 | c.856A>G p.M286V | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs779726694; called by muse, mutect2, varscan2
- NASP | c.478del p.T160Qfs*29 | Frame Shift Del (DEL) | VAF 50/172 reads (29%) | catalogued as COSV100601638; called by mutect2, pindel, varscan2
- NDUFA10 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 73/313 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs959745767, COSV53153890; called by muse, mutect2, varscan2
- NECTIN1 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as rs764371211; called by muse, mutect2, varscan2
- NFATC2IP | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs779163433, COSV100297630; called by muse, mutect2, varscan2
- NHSL1 | c.3470C>T p.A1157V | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs563130045, COSV58676812; called by muse, mutect2, varscan2
- NMRK1 | c.536del p.L179Cfs*7 | Frame Shift Del (DEL) | VAF 28/102 reads (27%) | catalogued as COSV100738050; called by mutect2, pindel
- NOL6 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.24); catalogued as COSV53046169; called by muse, mutect2, varscan2
- NPM2 | c.539del p.K180Sfs*9 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs770540772, COSV57076165; called by mutect2, varscan2
- NTN3 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1451202401; called by muse, mutect2, varscan2
- NUP214 | c.4133dup p.V1379Gfs*60 | Frame Shift Ins (INS) | VAF 48/171 reads (28%) | catalogued as rs780417788; called by mutect2, varscan2
- NUP42 | c.212dup p.S72Qfs*13 | Frame Shift Ins (INS) | VAF 33/158 reads (21%) | catalogued as rs758695627; called by mutect2, varscan2
- OR13A1 | c.812C>T p.T271I | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs1388790436, COSV65572503; called by muse, mutect2, varscan2
- OSBPL8 | c.354del p.E119Nfs*37 | Frame Shift Del (DEL) | VAF 20/123 reads (16%) | catalogued as rs1565866961, COSV53879345; called by mutect2, pindel, varscan2
- OTUD7A | c.2131C>T p.P711S (on ENST00000307050 / NM_001382637.1; = p.P704S on NM_130901.3) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.051); catalogued as rs1167990445; called by muse, mutect2, varscan2
- OVGP1 | c.1054dup p.A352Gfs*10 | Frame Shift Ins (INS) | VAF 13/66 reads (20%) | catalogued as rs763064364; called by mutect2, varscan2
- PAX7 | c.186G>T p.M62I | Missense Mutation (SNP) | VAF 117/446 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1394269546; called by muse, mutect2, varscan2
- PCDH10 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99993059; called by muse, mutect2, varscan2
- PCDH10 | c.1823C>T p.A608V | Missense Mutation (SNP) | VAF 59/224 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as rs1232072107, COSV52087921; called by muse, mutect2, varscan2
- PCDHA3 | c.1981G>A p.A661T | Missense Mutation (SNP) | VAF 72/247 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.145); catalogued as rs781920190, COSV63538916; called by muse, mutect2, varscan2
- PCDHA4 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 137/465 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.798); catalogued as rs1554124539, COSV63547367; called by muse, mutect2, varscan2
- PCDHB12 | c.2078C>T p.A693V | Missense Mutation (SNP) | VAF 114/416 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as COSV53396266, COSV53397223, COSV53401445; called by muse, mutect2, varscan2
- PCDHB15 | c.1347del p.A450Pfs*92 | Frame Shift Del (DEL) | VAF 110/487 reads (23%) | catalogued as rs782057508; called by mutect2, pindel, varscan2
- PCDHGA5 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 113/398 reads (28%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs777450935, COSV53945633; called by muse, mutect2, varscan2
- PCDHGB3 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 140/499 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.229); catalogued as rs372336757; called by muse, mutect2, varscan2
- PDE6A | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 92/382 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as rs373537826; called by muse, mutect2, varscan2
- PDX1 | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV101124091; called by muse, mutect2, varscan2
- PGR | c.2171G>T p.R724M | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54813647; called by muse, mutect2, varscan2
- PHF24 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as rs372732529; called by muse, mutect2, varscan2
- PIK3CA | c.2636A>G p.Q879R | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as COSV55928531; called by muse, mutect2, varscan2
- PIP4P2 | c.538del p.I180Sfs*21 | Frame Shift Del (DEL) | VAF 21/75 reads (28%) | catalogued as rs1158949501; called by mutect2, pindel, varscan2
- PLCD1 | c.1882C>T p.R628W | Missense Mutation (SNP) | VAF 117/507 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs760631515, COSV52186942; called by muse, mutect2, varscan2
- PLEC | c.6412G>A p.A2138T (on ENST00000322810 / NM_201380.4; = p.A2028T on NM_000445.5) | Missense Mutation (SNP) | VAF 30/634 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.389); catalogued as rs535202853, COSV59696123; ClinVar: uncertain significance; called by muse, mutect2
- PLXNA4 | c.3739G>A p.G1247S | Missense Mutation (SNP) | VAF 78/421 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.094); catalogued as rs773306424, COSV58113296; called by muse, mutect2, varscan2
- POP1 | c.985A>G p.I329V | Missense Mutation (SNP) | VAF 94/352 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as rs1435867132; called by muse, mutect2, varscan2
- POU3F3 | c.1090G>T p.E364* | Nonsense Mutation (SNP) | VAF 112/435 reads (26%) | catalogued as COSV63721611; called by muse, mutect2, varscan2
- POU6F1 | c.1538C>T p.P513L | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs375633440, COSV61326670; called by muse, mutect2, varscan2
- PPM1D | c.1535del p.N512Ifs*2 | Frame Shift Del (DEL) | VAF 75/280 reads (27%) | catalogued as rs763475304; called by mutect2, pindel, varscan2
- PPP1R13B | c.1598C>T p.A533V | Missense Mutation (SNP) | VAF 82/345 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as rs755869205; called by muse, mutect2, varscan2
- PPP1R2C | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 78/291 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as rs1448451090; called by muse, mutect2, varscan2
- PRKD3 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 67/265 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs1286077413, COSV52211462; called by muse, mutect2, varscan2
- PRKD3 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1441572576, COSV52210078; called by muse, mutect2
- PRMT9 | c.2210G>A p.R737H | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs138669035; called by muse, mutect2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 36/154 reads (23%) | catalogued as rs781858060; called by mutect2, varscan2
- PSMD4 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1292583615; called by muse, mutect2, varscan2
- PUF60 | c.680G>A p.R227H (on ENST00000526683 / NM_001362896.2; = p.R210H on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 113/404 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs1361458345; called by muse, varscan2
- PUM2 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57584568; called by muse, mutect2, varscan2
- PVR | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 88/328 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV51823284; called by muse, mutect2, varscan2
- RARS1 | c.8T>C p.V3A | Missense Mutation (SNP) | VAF 93/257 reads (36%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs1205277225; called by muse, mutect2, varscan2
- RBM14 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.672); catalogued as COSV59560527; called by muse, mutect2, varscan2
- RBM38 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 25/580 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs767638060, COSV100654910, COSV61134079; called by muse, mutect2
- RCSD1 | c.443del p.P148Lfs*18 | Frame Shift Del (DEL) | VAF 78/283 reads (28%) | catalogued as rs1558092785; called by mutect2, pindel, varscan2
- RECQL4 | c.2351G>A p.R784Q | Missense Mutation (SNP) | VAF 98/332 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as rs536096413, COSV99467458; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REPIN1 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 72/287 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs748725565, COSV68293072; called by muse, mutect2, varscan2
- RFC5 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1406442886; called by muse, mutect2, varscan2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs751982308; called by mutect2, varscan2
- RIC1 | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1226183162; called by muse, mutect2, varscan2
- RNF112 | c.371del p.P124Lfs*9 | Frame Shift Del (DEL) | VAF 42/178 reads (24%) | catalogued as rs11398287; called by mutect2, pindel, varscan2
- RNF220 | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.885); catalogued as rs144461708; called by muse, mutect2
- RPL17-C18orf32 | c.612G>A p.W204* | Nonsense Mutation (SNP) | VAF 21/112 reads (19%) | catalogued as rs972646924; called by muse, mutect2, varscan2
- RPS3A | c.589A>G p.I197V | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as rs1003985913; called by muse, mutect2, varscan2
- RTN4R | c.1378del p.L460Wfs*91 | Frame Shift Del (DEL) | VAF 34/208 reads (16%) | catalogued as rs1250787345; called by mutect2, varscan2
- SBNO1 | c.3416del p.N1139Mfs*9 (on ENST00000420886; = p.N1138Mfs*9 on NM_018183.5) | Frame Shift Del (DEL) | VAF 24/80 reads (30%) | catalogued as rs765867975; called by mutect2, varscan2
- SCARF2 | c.2138C>A p.T713K | Missense Mutation (SNP) | VAF 65/241 reads (27%) | SIFT tolerated (0.96); PolyPhen benign (0.023); catalogued as COSV56733344; called by muse, mutect2, varscan2
- SCLT1 | c.550-1G>T p.X184_splice | Splice Site (SNP) | VAF 5/12 reads (42%) | catalogued as rs773504787; called by muse, varscan2
- SEZ6L2 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.337); catalogued as rs1481824713; called by muse, varscan2
- SGO2 | c.1929del p.G644Vfs*18 | Frame Shift Del (DEL) | VAF 17/96 reads (18%) | catalogued as rs1260834379; called by mutect2, pindel, varscan2
- SH2B3 | c.1645C>T p.R549* | Nonsense Mutation (SNP) | VAF 79/278 reads (28%) | catalogued as rs548593303, COSV57983642; called by muse, mutect2, varscan2
- SIGLEC1 | c.1123del p.L375Sfs*33 | Frame Shift Del (DEL) | VAF 19/78 reads (24%) | catalogued as COSV52465511; called by mutect2, pindel, varscan2
- SIK2 | c.2362A>G p.S788G | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.024); catalogued as rs768730339; called by muse, mutect2, varscan2
- SLAMF1 | c.829del p.S277Afs*54 | Frame Shift Del (DEL) | VAF 38/164 reads (23%) | catalogued as rs751442558; called by mutect2, varscan2
- SLC12A8 | c.764dup p.D256Rfs*43 | Frame Shift Ins (INS) | VAF 43/199 reads (22%) | catalogued as rs771481014; called by mutect2, pindel, varscan2
- SLC13A2 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as rs782607614, COSV100120313; called by muse, mutect2, varscan2
- SLC22A16 | c.1309del p.Q437Rfs*9 | Frame Shift Del (DEL) | VAF 30/104 reads (29%) | catalogued as rs1350502800; called by mutect2, pindel, varscan2
- SLC35E3 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV57493642; called by muse, mutect2, varscan2
- SLC4A11 | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 122/464 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.253); catalogued as COSV66262890; called by muse, mutect2, varscan2
- SLC4A5 | c.2453G>A p.G818D | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1351336447; called by muse, mutect2, varscan2
- SLC6A15 | c.626G>T p.R209M | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99879925, COSV99880860; called by muse, mutect2
- SLC9A3R1 | c.799_801del p.X267_splice | Splice Site (DEL) | VAF 68/332 reads (20%) | catalogued as rs746594959; called by pindel, varscan2
- SMAP1 | c.515del p.K172Rfs*48 (on ENST00000370455 / NM_001044305.3; = p.K145Rfs*48 on NM_021940.5) | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | catalogued as rs763364024; called by mutect2, varscan2
- SMARCB1 | c.214del p.T72Qfs*13 | Frame Shift Del (DEL) | VAF 99/374 reads (26%) | catalogued as COSV99574633; called by mutect2, varscan2
- SMPX | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 92/333 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs200892029; called by muse, mutect2, varscan2
- SOX7 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs370726272; called by muse, mutect2, varscan2
- SPIDR | c.698C>T p.T233I | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs1306793411; called by muse, mutect2, varscan2
- SPPL2C | c.1373A>G p.Y458C | Missense Mutation (SNP) | VAF 85/295 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs149883602; called by muse, mutect2, varscan2
- SS18 | c.278G>A p.S93N | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as rs751664363; called by muse, mutect2, varscan2
- ST13 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs1405938904; called by muse, mutect2, varscan2
- ST8SIA5 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 95/346 reads (27%) | PolyPhen possibly damaging (0.754); catalogued as rs1274598306, COSV59330703; called by muse, mutect2, varscan2
- STAG2 | c.2096+1G>T p.X699_splice | Splice Site (SNP) | VAF 10/33 reads (30%) | catalogued as COSV54351796; called by muse, mutect2, varscan2
- STARD8 | c.2618del p.P873Qfs*28 | Frame Shift Del (DEL) | VAF 62/230 reads (27%) | catalogued as rs761897392; called by mutect2, varscan2
- STARD9 | c.11207G>A p.S3736N | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.844); catalogued as rs1286303988; called by muse, mutect2, varscan2
- SYCP2 | c.3071del p.N1024Tfs*26 | Frame Shift Del (DEL) | VAF 26/106 reads (25%) | catalogued as rs753462162; called by mutect2, varscan2
- SYDE1 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as rs1346103018; called by muse, mutect2, varscan2
- TARS2 | c.1591G>A p.G531R | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757886501, COSV64695211; called by muse, mutect2, varscan2
- TBCC | c.390del p.L131Cfs*22 | Frame Shift Del (DEL) | VAF 30/128 reads (23%) | catalogued as rs772145297; called by mutect2, pindel, varscan2
- TBK1 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs758384241; called by muse, mutect2, varscan2
- TBKBP1 | c.727del p.A243Lfs*19 | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | catalogued as COSV64653259; called by mutect2, pindel, varscan2
- TBX3 | c.1307G>A p.R436H (on ENST00000257566 / NM_016569.4; = p.R416H on NM_005996.4) | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.719); catalogued as COSV57470202, COSV57470303; called by muse, mutect2, varscan2
- TCF4 | c.1940del p.P647Lfs*32 | Frame Shift Del (DEL) | VAF 50/228 reads (22%) | catalogued as COSV61906772; called by pindel, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 47/150 reads (31%) | catalogued as rs763321097; called by mutect2, varscan2
- THRAP3 | c.1243C>T p.R415* | Nonsense Mutation (SNP) | VAF 20/78 reads (26%) | catalogued as COSV63570012; called by muse, mutect2, varscan2
- THSD1 | c.1282A>G p.I428V | Missense Mutation (SNP) | VAF 55/259 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51626457; called by muse, mutect2, varscan2
- TJP2 | c.1521C>T p.G507= | Splice Region (SNP) | VAF 36/196 reads (18%) | catalogued as rs1226597937; called by muse, mutect2, varscan2
- TMEM196 | c.192del p.K64Nfs*6 | Frame Shift Del (DEL) | VAF 17/98 reads (17%) | catalogued as rs759398828; called by mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 24/80 reads (30%) | catalogued as rs749773249; called by mutect2, varscan2
- TNRC18 | c.4627dup p.R1543Pfs*10 | Frame Shift Ins (INS) | VAF 30/98 reads (31%) | catalogued as rs754233336; called by mutect2, varscan2
- TNRC6B | c.1249C>T p.R417* | Nonsense Mutation (SNP) | VAF 33/99 reads (33%) | catalogued as COSV57294459; called by muse, mutect2, varscan2
- TNS1 | c.2918del p.P973Rfs*13 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | catalogued as COSV50692006; called by mutect2, pindel, varscan2
- TRAF3IP3 | c.1478A>G p.N493S | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs1306183518; called by muse, mutect2, varscan2
- TRIM24 | c.2587G>T p.G863* (on ENST00000343526 / NM_015905.3; = p.G829* on NM_003852.4) | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV58971852; called by muse, mutect2, varscan2
- TRIM71 | c.2536G>A p.G846S | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs1206088653, COSV67471332; called by muse, mutect2, varscan2
- TRIM73 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs587741041; called by mutect2, varscan2
- TRIML2 | c.135G>T p.Q45H | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV100456457; called by muse, mutect2, varscan2
- TSC2 | c.3209C>T p.T1070M | Missense Mutation (SNP) | VAF 140/504 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs147989574; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- U2AF1L4 | c.466C>T p.R156C (on ENST00000412391; = p.R117C on NM_001040425.3) | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs770561205, COSV99494940; called by muse, mutect2, varscan2
- UBXN6 | c.966G>A p.M322I | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV56674438; called by muse, mutect2, varscan2
- USP31 | c.2194G>A p.V732M | Missense Mutation (SNP) | VAF 27/562 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99565674; called by muse, mutect2
- USP35 | c.1059del p.M354Wfs*119 | Frame Shift Del (DEL) | VAF 19/54 reads (35%) | catalogued as rs761345427; called by mutect2, pindel, varscan2
- UVSSA | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs756645260, COSV66230382; called by muse, mutect2, varscan2
- VPS13C | c.4429del p.I1477Lfs*24 (on ENST00000644861 / NM_020821.3; = p.I1434Lfs*24 on NM_017684.5) | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | catalogued as rs756149444; called by mutect2, varscan2
- WDFY4 | c.7396G>A p.A2466T | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as rs977029050; called by muse, mutect2, varscan2
- WDR18 | c.696del p.C232Wfs*41 | Frame Shift Del (DEL) | VAF 22/99 reads (22%) | catalogued as COSV52124099; called by mutect2, pindel, varscan2
- WDR24 | c.1184A>G p.H395R (on ENST00000248142; = p.H265R on NM_032259.4) | Missense Mutation (SNP) | VAF 68/233 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs917064151, COSV50196390; called by muse, mutect2, varscan2
- WDR6 | c.2449A>G p.M817V | Missense Mutation (SNP) | VAF 81/285 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1445202575; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 24/125 reads (19%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 50/184 reads (27%) | catalogued as rs762079039; called by mutect2, varscan2
- XIRP1 | c.2743C>T p.R915W | Missense Mutation (SNP) | VAF 58/199 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs757755625; called by muse, mutect2, varscan2
- ZC3H18 | c.2037del p.R680Gfs*5 | Frame Shift Del (DEL) | VAF 17/102 reads (17%) | catalogued as rs751577786; called by mutect2, varscan2
- ZFAT | c.3329C>T p.A1110V | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs773605523, COSV64736169; called by muse, mutect2, varscan2
- ZMYM2 | c.3131del p.K1044Rfs*33 | Frame Shift Del (DEL) | VAF 25/101 reads (25%) | catalogued as rs753611080; called by mutect2, varscan2
- ZNF132 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as rs769038063; called by muse, mutect2, varscan2
- ZNF280D | c.2223del p.E742Kfs*62 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | catalogued as rs1158517703; called by mutect2, pindel, varscan2
- ZNF292 | c.4450C>T p.Q1484* | Nonsense Mutation (SNP) | VAF 46/145 reads (32%) | catalogued as COSV60535970; called by muse, mutect2, varscan2
- ZNF341 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.499); catalogued as rs567905770, COSV61007362; called by muse, mutect2, varscan2
- ZNF394 | c.1307A>G p.H436R | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1226260657; called by muse, mutect2, varscan2
- ZNF444 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 89/339 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs745426327; called by muse, mutect2, varscan2
- ZNF516 | c.1720G>T p.A574S | Missense Mutation (SNP) | VAF 102/376 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.123); catalogued as rs780359683; called by muse, mutect2, varscan2
- ZNF516 | c.1202C>T p.T401M | Missense Mutation (SNP) | VAF 75/296 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as rs1262488570; called by muse, mutect2, varscan2
- ZNF644 | c.871del p.R291Efs*7 | Frame Shift Del (DEL) | VAF 26/84 reads (31%) | catalogued as rs749473342; called by mutect2, varscan2
- ZNF672 | c.226G>T p.G76* | Nonsense Mutation (SNP) | VAF 108/391 reads (28%) | catalogued as COSV60637590; called by muse, mutect2, varscan2
- ZNF672 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV60638195; called by muse, mutect2, varscan2
- ZNF737 | c.344del p.K115Rfs*6 | Frame Shift Del (DEL) | VAF 16/87 reads (18%) | catalogued as COSV71200930; called by mutect2, pindel, varscan2
- ZNF76 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 74/233 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0.035); catalogued as rs370083681; called by muse, mutect2, varscan2
- ZNF827 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs780004872, COSV65226939; called by muse, mutect2, varscan2
- ZNF99 | c.1373G>A p.C458Y | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764305477, COSV68055885; called by muse, mutect2, varscan2
- ZPBP2 | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as rs762975536; called by muse, mutect2, varscan2
- ZSCAN12 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs950973823; called by muse, mutect2, varscan2
- ZSCAN22 | c.1124C>T p.T375M | Missense Mutation (SNP) | VAF 77/243 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs200006267; called by muse, mutect2, varscan2
- AADACL3 | c.1088T>C p.L363P | Missense Mutation (SNP) | VAF 74/237 reads (31%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ABCC6 | c.2495C>T p.A832V | Missense Mutation (SNP) | VAF 82/268 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ABL2 | c.1021C>T p.H341Y (on ENST00000502732 / NM_007314.4; = p.H326Y on NM_005158.5) | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACRBP | c.263-2A>G p.X88_splice | Splice Site (SNP) | VAF 30/121 reads (25%) | called by muse, mutect2, varscan2
- ADCY7 | c.409T>C p.Y137H | Missense Mutation (SNP) | VAF 98/382 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- ADGRL1 | c.4141C>T p.R1381W (on ENST00000340736 / NM_001008701.3; = p.R1376W on NM_014921.5) | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRV1 | c.18029A>G p.Y6010C | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ADRB2 | c.454del p.V152* | Frame Shift Del (DEL) | VAF 94/381 reads (25%) | called by mutect2, pindel, varscan2
- AFDN | c.3219-2A>G p.X1073_splice | Splice Site (SNP) | VAF 43/118 reads (36%) | called by muse, mutect2, varscan2
- ANKRD11 | c.4832T>C p.L1611P | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2
- ANKRD11 | c.1794del p.H598Qfs*55 | Frame Shift Del (DEL) | VAF 40/172 reads (23%) | called by mutect2, pindel, varscan2
- ARF5 | c.493G>T p.G165C | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP35 | c.2725del p.E909Rfs*39 | Frame Shift Del (DEL) | VAF 27/140 reads (19%) | called by mutect2, pindel, varscan2
- ARHGEF11 | c.2296_2298del p.K766del | In Frame Del (DEL) | VAF 17/101 reads (17%) | called by pindel, varscan2
- ARSF | c.1648T>C p.Y550H | Missense Mutation (SNP) | VAF 79/284 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARSK | c.324T>A p.N108K | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- ARX | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 71/284 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ASIC4 | c.1172+3_1172+4del p.X391_splice (on ENST00000347842 / NM_182847.3; = p.X410_splice on NM_018674.6) | Splice Site (DEL) | VAF 18/72 reads (25%) | called by mutect2, pindel, varscan2
- ATAD2 | c.1330T>C p.F444L | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ATAD5 | c.1433T>C p.L478P | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ATAD5 | c.4911del p.K1637Nfs*10 | Frame Shift Del (DEL) | VAF 29/129 reads (22%) | called by mutect2, pindel, varscan2
- ATM | c.3475G>A p.A1159T | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ATP5PD | c.39G>A p.W13* | Nonsense Mutation (SNP) | VAF 32/171 reads (19%) | called by muse, mutect2, varscan2
- ATP6V0D1 | c.1040A>G p.Y347C | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATRN | c.3934C>T p.R1312C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AVEN | c.77G>A p.S26N | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- AVPR2 | c.738del p.R247Afs*24 | Frame Shift Del (DEL) | VAF 48/172 reads (28%) | called by mutect2, pindel, varscan2
- BAIAP3 | c.2314-1G>T p.X772_splice | Splice Site (SNP) | VAF 24/89 reads (27%) | called by muse, mutect2, varscan2
- BAZ2B | c.3056A>G p.E1019G | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BICRA | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.097); called by muse, mutect2
- BICRA | c.2003C>A p.P668H | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, varscan2
- BLCAP | c.199C>A p.L67M | Missense Mutation (SNP) | VAF 78/282 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- BOD1L1 | c.8494A>G p.T2832A | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRD4 | c.51G>T p.M17I | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- C11orf49 | c.275del p.N92Mfs*5 | Frame Shift Del (DEL) | VAF 44/147 reads (30%) | called by mutect2, pindel, varscan2
- C2orf16 | c.699del p.Q234Rfs*23 | Frame Shift Del (DEL) | VAF 37/138 reads (27%) | called by mutect2, pindel, varscan2
- CAMKV | c.296T>C p.L99P | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CASP8AP2 | c.3707del p.N1236Ifs*9 | Frame Shift Del (DEL) | VAF 27/91 reads (30%) | called by mutect2, varscan2
- CBARP | c.155del p.G52Afs*114 (on ENST00000382477; = p.G58Afs*98 on NM_152769.3) | Frame Shift Del (DEL) | VAF 35/146 reads (24%) | called by mutect2, varscan2
- CBX8 | c.956del p.G319Afs*37 | Frame Shift Del (DEL) | VAF 26/88 reads (30%) | called by mutect2, varscan2
- CCDC178 | c.1525_1526del p.F509Pfs*9 | Frame Shift Del (DEL) | VAF 13/69 reads (19%) | called by mutect2, pindel, varscan2
- CD69 | c.440del p.K147Rfs*30 | Frame Shift Del (DEL) | VAF 58/282 reads (21%) | called by mutect2, pindel, varscan2
- CDK5RAP2 | c.4538G>A p.S1513N | Missense Mutation (SNP) | VAF 84/371 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CEBPZ | c.2174C>A p.P725H | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CEP152 | c.3829del p.I1277Lfs*20 (on ENST00000380950 / NM_001194998.2; = p.I1221Lfs*20 on NM_014985.4) | Frame Shift Del (DEL) | VAF 73/278 reads (26%) | called by mutect2, varscan2
- CEP63 | c.2074_2075dup p.S692Rfs*6 | Frame Shift Ins (INS) | VAF 24/194 reads (12%) | called by mutect2, varscan2
- CFAP91 | c.1912G>A p.V638I | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, varscan2
- CHD3 | c.1071_1072dup p.K358Rfs*127 | Frame Shift Ins (INS) | VAF 21/89 reads (24%) | called by mutect2, pindel, varscan2
- CHRDL1 | c.1007G>A p.C336Y (on ENST00000372045; = p.C342Y on NM_145234.4) | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- CHRNE | c.341del p.N114Tfs*23 | Frame Shift Del (DEL) | VAF 122/484 reads (25%) | called by mutect2, varscan2
- CHTF8 | c.141+5G>T | Splice Region (SNP) | VAF 101/358 reads (28%) | called by muse, mutect2, varscan2
- CIAO3 | c.755A>G p.E252G | Missense Mutation (SNP) | VAF 49/227 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CILP2 | c.1843C>A p.L615I | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CLCNKB | c.947G>A p.S316N | Missense Mutation (SNP) | VAF 90/579 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- CNKSR1 | c.1225T>C p.W409R (on ENST00000374253 / NM_001297647.2; = p.W402R on NM_006314.3) | Missense Mutation (SNP) | VAF 86/287 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTN4 | c.1055del p.N352Mfs*6 | Frame Shift Del (DEL) | VAF 49/185 reads (26%) | called by mutect2, pindel, varscan2
- COG3 | c.1146A>T p.Q382H | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- COL11A2 | c.4996C>G p.L1666V (on ENST00000341947 / NM_080680.3; = p.L1559V on NM_080679.2) | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- COL1A1 | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, varscan2
- COL4A3 | c.2747-1G>A p.X916_splice | Splice Site (SNP) | VAF 40/197 reads (20%) | called by muse, mutect2, varscan2
- COLGALT1 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COQ6 | c.1327T>A p.L443M | Missense Mutation (SNP) | VAF 13/330 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.358); called by muse, mutect2
- CORIN | c.434G>A p.S145N | Missense Mutation (SNP) | VAF 66/206 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- CORO6 | c.1359G>T p.Q453H | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CPD | c.690dup p.A231Rfs*38 | Frame Shift Ins (INS) | VAF 27/126 reads (21%) | called by mutect2, pindel, varscan2
- CREB3 | c.782-2A>G p.X261_splice | Splice Site (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- CSNK1E | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CTCF | c.610del p.T204Qfs*18 | Frame Shift Del (DEL) | VAF 116/474 reads (24%) | called by mutect2, pindel, varscan2
- CTDP1 | c.697C>A p.L233M | Missense Mutation (SNP) | VAF 27/392 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CUL5 | c.503del p.L168Wfs*13 | Frame Shift Del (DEL) | VAF 27/126 reads (21%) | called by mutect2, pindel, varscan2
- CUX1 | c.1834C>T p.Q612* | Nonsense Mutation (SNP) | VAF 42/158 reads (27%) | called by muse, mutect2, varscan2
- CYP7A1 | c.1325C>T p.T442I | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- DAB2IP | c.223G>A p.V75I (on ENST00000408936; = p.V47I on NM_032552.3) | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- DACH2 | c.884del p.G295Vfs*14 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- DBN1 | c.292T>C p.C98R | Missense Mutation (SNP) | VAF 85/312 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DEDD | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 90/324 reads (28%) | called by muse, mutect2, varscan2
- DEDD2 | c.890T>C p.V297A | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2
- DENND5A | c.2903del p.G968Afs*29 | Frame Shift Del (DEL) | VAF 37/185 reads (20%) | called by mutect2, pindel, varscan2
- DGKD | c.1336T>C p.W446R (on ENST00000264057 / NM_152879.3; = p.W402R on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DLST | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- DMTF1 | c.1244dup p.N415Kfs*9 | Frame Shift Ins (INS) | VAF 44/200 reads (22%) | called by mutect2, varscan2
- DNAH2 | c.3423C>G p.H1141Q | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJA1 | c.975+1_975+5del p.X325_splice | Splice Site (DEL) | VAF 19/81 reads (23%) | called by mutect2, pindel, varscan2
- DOCK8 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 64/267 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- DPH7 | c.619C>T p.H207Y | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- DVL1 | c.751A>G p.T251A | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- E2F4 | c.1160del p.P387Rfs*29 | Frame Shift Del (DEL) | VAF 44/203 reads (22%) | called by mutect2, pindel, varscan2
- ECEL1 | c.334C>A p.L112M | Missense Mutation (SNP) | VAF 18/381 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.523); called by muse, mutect2
- EDC4 | c.3161-2A>T p.X1054_splice | Splice Site (SNP) | VAF 47/162 reads (29%) | called by muse, mutect2, varscan2
- EEF2K | c.837_838del p.D280Sfs*4 | Frame Shift Del (DEL) | VAF 43/229 reads (19%) | called by mutect2, pindel, varscan2
- EOMES | c.579del p.G194Afs*94 | Frame Shift Del (DEL) | VAF 42/210 reads (20%) | called by mutect2, pindel, varscan2
- ERC2 | c.371T>C p.L124P | Missense Mutation (SNP) | VAF 77/244 reads (32%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ERN2 | c.2077C>T p.Q693* | Nonsense Mutation (SNP) | VAF 49/129 reads (38%) | called by muse, varscan2
- FAM117B | c.1547G>T p.S516I | Missense Mutation (SNP) | VAF 103/333 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM122B | c.178-1G>T p.X60_splice | Splice Site (SNP) | VAF 45/190 reads (24%) | called by muse, mutect2, varscan2
- FAM13B | c.127del p.R43Afs*76 | Frame Shift Del (DEL) | VAF 42/147 reads (29%) | called by mutect2, pindel, varscan2
- FAM171A2 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FAM178B | c.697C>A p.L233I | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- FAM214B | c.1002del p.S335Vfs*77 | Frame Shift Del (DEL) | VAF 53/216 reads (25%) | called by mutect2, pindel, varscan2
- FAT3 | c.8012del p.N2671Ifs*11 | Frame Shift Del (DEL) | VAF 18/95 reads (19%) | called by mutect2, pindel, varscan2
- FBN2 | c.6254del p.P2085Lfs*164 | Frame Shift Del (DEL) | VAF 52/222 reads (23%) | called by mutect2, pindel, varscan2
- FBXO38 | c.2090del p.N697Tfs*32 | Frame Shift Del (DEL) | VAF 54/170 reads (32%) | called by mutect2, varscan2
- FBXW8 | c.231G>T p.Q77H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- FCGBP | c.6719G>A p.C2240Y | Missense Mutation (SNP) | VAF 56/1546 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- FCGBP | c.1768G>A p.D590N | Missense Mutation (SNP) | VAF 80/322 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- FGFR3 | c.546del p.T183Lfs*7 | Frame Shift Del (DEL) | VAF 76/338 reads (22%) | called by mutect2, pindel, varscan2
- FLNC | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 84/312 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FLOT1 | c.128_129del p.L43Qfs*10 | Frame Shift Del (DEL) | VAF 44/220 reads (20%) | called by pindel, varscan2
- FMNL2 | c.1720C>T p.L574F | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- FOXD4L4 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 223/939 reads (24%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXP2 | c.1297A>G p.K433E | Missense Mutation (SNP) | VAF 81/291 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- FSD1L | c.617_618del p.E206Vfs*6 | Frame Shift Del (DEL) | VAF 37/220 reads (17%) | called by pindel, varscan2
- GAB1 | c.1507del p.T503Pfs*32 | Frame Shift Del (DEL) | VAF 37/144 reads (26%) | called by mutect2, pindel, varscan2
- GABBR2 | c.184A>G p.M62V | Missense Mutation (SNP) | VAF 56/211 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- GANAB | c.1706G>T p.R569L | Missense Mutation (SNP) | VAF 61/274 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- GAPDHS | c.632A>G p.Y211C | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GATA5 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GBA2 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); called by muse, mutect2
- GCC2 | c.2106del p.K702Nfs*3 | Frame Shift Del (DEL) | VAF 17/43 reads (40%) | called by mutect2, varscan2
- GFUS | c.15G>T p.Q5H | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- GIMAP7 | c.463del p.S155Afs*34 | Frame Shift Del (DEL) | VAF 97/440 reads (22%) | called by mutect2, pindel, varscan2
- GNAI1 | c.1008del p.F336Lfs*4 | Frame Shift Del (DEL) | VAF 21/81 reads (26%) | called by mutect2, pindel, varscan2
- GPR180 | c.472A>C p.N158H | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR25 | c.763G>T p.G255C | Missense Mutation (SNP) | VAF 67/267 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GPR85 | c.473del p.L158* | Frame Shift Del (DEL) | VAF 56/220 reads (25%) | called by mutect2, pindel, varscan2
- GPS1 | c.690_691del p.E230Dfs*9 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | called by pindel, varscan2
- GRHL3 | c.236G>A p.S79N (on ENST00000350501 / NM_198174.3; = p.S84N on NM_021180.3) | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- GRID2IP | c.158A>T p.E53V | Missense Mutation (SNP) | VAF 111/369 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRM3 | c.1861G>T p.G621W | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GSPT1 | c.137G>A p.S46N (on ENST00000420576 / NM_001130007.2; = p.S184N on NM_002094.4) | Missense Mutation (SNP) | VAF 103/435 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- GTPBP2 | c.88del p.A30Pfs*43 | Frame Shift Del (DEL) | VAF 26/89 reads (29%) | called by mutect2, pindel, varscan2
- GUCY1A1 | c.1339A>G p.K447E | Missense Mutation (SNP) | VAF 88/246 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HAUS6 | c.2133G>A p.M711I | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- HCCS | c.628A>G p.R210G | Missense Mutation (SNP) | VAF 66/228 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HERC6 | c.1056del p.F352Lfs*9 | Frame Shift Del (DEL) | VAF 33/112 reads (29%) | called by mutect2, pindel, varscan2
- HHIPL1 | c.358C>T p.H120Y | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- HIVEP1 | c.1206del p.K402Nfs*21 | Frame Shift Del (DEL) | VAF 26/102 reads (25%) | called by mutect2, pindel, varscan2
- HIVEP2 | c.6416C>T p.T2139I | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.109); called by muse, mutect2
- HNRNPA2B1 | c.757G>T p.G253C (on ENST00000354667 / NM_031243.3; = p.G241C on NM_002137.4) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- HSPG2 | c.1391T>C p.L464P | Missense Mutation (SNP) | VAF 157/525 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTT | c.2096del p.N699Mfs*9 | Frame Shift Del (DEL) | VAF 38/181 reads (21%) | called by mutect2, pindel, varscan2
- HUWE1 | c.9068C>T p.A3023V | Missense Mutation (SNP) | VAF 119/442 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HYI | c.907T>C p.*303Rext*? (on ENST00000372434 / NM_001330526.2; = p.*278Rext*? on NM_001190880.2) | Nonstop Mutation (SNP) | VAF 65/213 reads (31%) | called by muse, mutect2, varscan2
- IFNGR2 | c.727A>G p.T243A | Missense Mutation (SNP) | VAF 61/284 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- IFNL2 | c.193-1G>T p.X65_splice | Splice Site (SNP) | VAF 51/179 reads (28%) | called by muse, mutect2, varscan2
- IFRD2 | c.46del p.A16Rfs*39 | Frame Shift Del (DEL) | VAF 65/324 reads (20%) | called by mutect2, pindel, varscan2
- IGF2R | c.5468G>A p.S1823N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL17RA | c.2300del p.G767Afs*70 | Frame Shift Del (DEL) | VAF 125/577 reads (22%) | called by mutect2, pindel, varscan2
- ILVBL | c.12del p.A5Rfs*58 | Frame Shift Del (DEL) | VAF 28/132 reads (21%) | called by mutect2, pindel, varscan2
- ING3 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- INTU | c.1305del p.F435Lfs*33 | Frame Shift Del (DEL) | VAF 20/108 reads (19%) | called by mutect2, pindel, varscan2
- IQSEC3 | c.2600A>G p.H867R (on ENST00000538872 / NM_001170738.2; = p.H564R on NM_015232.1) | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- IRAK1 | c.1619del p.P540Lfs*53 | Frame Shift Del (DEL) | VAF 49/184 reads (27%) | called by mutect2, pindel, varscan2
- IRAK3 | c.382-2A>G p.X128_splice | Splice Site (SNP) | VAF 31/111 reads (28%) | called by muse, mutect2, varscan2
- IRF2BP1 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 110/404 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- IRS1 | c.3685T>C p.Y1229H | Missense Mutation (SNP) | VAF 72/241 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IRS2 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 80/254 reads (31%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- IRX5 | c.713del p.P238Lfs*129 | Frame Shift Del (DEL) | VAF 115/444 reads (26%) | called by mutect2, pindel, varscan2
- JUNB | c.740C>A p.P247Q | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNA4 | c.343_345del p.E115del | In Frame Del (DEL) | VAF 57/194 reads (29%) | called by pindel, varscan2
- KCNJ16 | c.1174dup p.S392Ffs*5 | Frame Shift Ins (INS) | VAF 54/183 reads (30%) | called by mutect2, pindel, varscan2
- KCP | c.4346C>T p.A1449V (on ENST00000620378; = p.A1573V on NM_001366122.1) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- KCTD16 | c.719T>C p.L240S | Missense Mutation (SNP) | VAF 80/260 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- KIR3DL1 | c.1105del p.N369Mfs*4 | Frame Shift Del (DEL) | VAF 44/248 reads (18%) | called by mutect2, varscan2
- KLC3 | c.324G>T p.Q108H | Missense Mutation (SNP) | VAF 92/238 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KLHDC8B | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 79/244 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- KLHL31 | c.312dup p.D105Rfs*11 | Frame Shift Ins (INS) | VAF 21/170 reads (12%) | called by mutect2, varscan2
- KLHL34 | c.1120del p.E374Rfs*219 | Frame Shift Del (DEL) | VAF 52/215 reads (24%) | called by mutect2, pindel, varscan2
- KLK5 | c.415T>A p.S139T | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- KRIT1 | c.130G>T p.G44* | Nonsense Mutation (SNP) | VAF 9/136 reads (7%) | called by muse, mutect2
- LCK | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- LILRA2 | c.1115A>G p.Q372R | Missense Mutation (SNP) | VAF 91/390 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LILRB5 | c.1450C>T p.H484Y (on ENST00000449561 / NM_001081442.3; = p.H483Y on NM_006840.5) | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- LMX1B | c.85A>G p.K29E | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- LRP8 | c.809G>A p.G270D | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC14B | c.47T>C p.V16A | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- LRRC74A | c.847A>G p.M283V | Missense Mutation (SNP) | VAF 69/255 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- LRRK2 | c.1633C>A p.L545M | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MAP3K20 | c.489_490del p.M164Vfs*24 | Frame Shift Del (DEL) | VAF 35/183 reads (19%) | called by pindel, varscan2
- MCM3AP | c.3832G>T p.A1278S | Missense Mutation (SNP) | VAF 111/450 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- MCM3AP | c.1910G>A p.C637Y | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MFSD12 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 136/434 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- MFSD14B | c.204+2dup p.X68_splice | Splice Site (INS) | VAF 52/220 reads (24%) | called by mutect2, pindel, varscan2
- MFSD4B | c.61dup p.T21Nfs*404 (on ENST00000368847; = p.D116Efs*26 on NM_153369.4) | Frame Shift Ins (INS) | VAF 18/127 reads (14%) | called by mutect2, pindel, varscan2
- MGAT1 | c.252del p.R85Gfs*15 | Frame Shift Del (DEL) | VAF 33/102 reads (32%) | called by mutect2, pindel, varscan2
- MIB1 | c.2239dup p.A747Gfs*19 | Frame Shift Ins (INS) | VAF 26/114 reads (23%) | called by mutect2, pindel
- MKI67 | c.7238T>C p.L2413P | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MLN | c.160T>A p.W54R | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTMR6 | c.216C>G p.C72W | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC16 | c.7094C>T p.S2365L | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- MYH14 | c.3776G>A p.S1259N | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- MYH4 | c.2728G>A p.D910N | Missense Mutation (SNP) | VAF 80/254 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- MYO15B | c.3239G>A p.G1080D | Missense Mutation (SNP) | VAF 58/241 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- MYO1A | c.2486G>A p.C829Y | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NCKAP5 | c.5291T>C p.M1764T | Missense Mutation (SNP) | VAF 77/255 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NDST1 | c.695del p.H232Pfs*54 | Frame Shift Del (DEL) | VAF 69/233 reads (30%) | called by mutect2, pindel, varscan2
- NDUFB8 | c.442del p.D148Tfs*51 | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | called by mutect2, pindel
- NDUFS1 | c.1413dup p.P472Tfs*14 | Frame Shift Ins (INS) | VAF 25/90 reads (28%) | called by mutect2, pindel, varscan2
- NEBL | c.2818C>T p.H940Y | Missense Mutation (SNP) | VAF 126/454 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- NEDD4 | c.2090G>A p.S697N (on ENST00000508342 / NM_001284338.1; = p.S278N on NM_006154.4) | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NGF | c.660del p.W220Cfs*6 | Frame Shift Del (DEL) | VAF 14/87 reads (16%) | called by pindel, varscan2
- NKAPL | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 48/159 reads (30%) | called by muse, mutect2, varscan2
- NLRP8 | c.692A>C p.K231T | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.045); called by muse, mutect2
- NOL11 | c.1108C>T p.L370F | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NOS1AP | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 96/306 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NOS3 | c.222G>T p.W74C | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NOSIP | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); called by muse, mutect2
- NOTCH4 | c.922G>T p.G308C | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPPB | c.10del p.Q4Rfs*79 | Frame Shift Del (DEL) | VAF 47/218 reads (22%) | called by mutect2, pindel, varscan2
- NTRK1 | c.466C>A p.L156M | Missense Mutation (SNP) | VAF 42/382 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NUB1 | c.357del p.D120Ifs*17 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | called by mutect2, pindel, varscan2
- NUPR2 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 69/251 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR14J1 | c.196_197del p.L66Sfs*53 | Frame Shift Del (DEL) | VAF 40/206 reads (19%) | called by pindel, varscan2
- OXSM | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 68/246 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PACS2 | c.895dup p.S299Kfs*10 | Frame Shift Ins (INS) | VAF 43/177 reads (24%) | called by mutect2, pindel, varscan2
- PACSIN1 | c.554C>A p.P185H | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- PAGE2 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAQR9 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 104/408 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- PCDH15 | c.4816G>A p.A1606T (on ENST00000644397 / NM_001354429.2; = p.A1548T on NM_001142771.2) | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHGA7 | c.1121G>T p.R374I | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- PCLO | c.11157dup p.V3720Sfs*2 | Frame Shift Ins (INS) | VAF 26/113 reads (23%) | called by mutect2, pindel, varscan2
- PCNX2 | c.1061T>C p.V354A | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- PDE2A | c.909G>T p.K303N | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- PER2 | c.2445del p.V817Cfs*10 | Frame Shift Del (DEL) | VAF 34/138 reads (25%) | called by mutect2, pindel, varscan2
- PICK1 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 100/351 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PIGU | c.989del p.P330Rfs*23 | Frame Shift Del (DEL) | VAF 73/354 reads (21%) | called by mutect2, pindel, varscan2
- PIWIL4 | c.1156A>T p.T386S | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.011); called by muse, mutect2
- PKP4 | c.1797del p.F599Lfs*10 | Frame Shift Del (DEL) | VAF 21/61 reads (34%) | called by mutect2, pindel, varscan2
- PLAGL1 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.083); called by muse, varscan2
- PLCE1 | c.3388G>T p.E1130* | Nonsense Mutation (SNP) | VAF 76/288 reads (26%) | called by muse, mutect2, varscan2
- PLEKHA4 | c.2176G>A p.V726M | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- PLXNA2 | c.342_344del p.N114del | In Frame Del (DEL) | VAF 63/222 reads (28%) | called by pindel, varscan2
- PNISR | c.311del p.P104Lfs*58 | Frame Shift Del (DEL) | VAF 39/182 reads (21%) | called by mutect2, pindel, varscan2
- PODXL | c.1249+1G>T p.X417_splice (on ENST00000378555 / NM_001018111.3; = p.X385_splice on NM_005397.4) | Splice Site (SNP) | VAF 14/71 reads (20%) | called by muse, mutect2, varscan2
- POLA1 | c.3451del p.S1151Afs*11 | Frame Shift Del (DEL) | VAF 27/133 reads (20%) | called by mutect2, pindel, varscan2
- POLE | c.1898A>G p.N633S | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPARA | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 68/270 reads (25%) | called by muse, mutect2, varscan2
- PPP6R3 | c.1785+2dup p.X595_splice (on ENST00000393800 / NM_001352375.2; = p.X515_splice on NM_018312.5) | Splice Site (INS) | VAF 7/22 reads (32%) | called by mutect2, varscan2
- PRDM4 | c.1277-1G>T p.X426_splice | Splice Site (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- PRUNE2 | c.8893G>T p.G2965C | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSMD2 | c.2257G>A p.A753T | Missense Mutation (SNP) | VAF 89/239 reads (37%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PTEN | c.608_609del p.I203Tfs*39 | Frame Shift Del (DEL) | VAF 53/178 reads (30%) | called by mutect2, pindel, varscan2
- PTEN | c.918dup p.E307Rfs*5 | Frame Shift Ins (INS) | VAF 41/216 reads (19%) | called by pindel, varscan2
- PTH1R | c.1127T>C p.I376T | Missense Mutation (SNP) | VAF 59/226 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- R3HDM2 | c.1187G>C p.R396P | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, varscan2
- RAB9B | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RADIL | c.3070del p.D1024Tfs*6 | Frame Shift Del (DEL) | VAF 44/187 reads (24%) | called by mutect2, pindel, varscan2
- RASSF4 | c.551C>G p.A184G | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- RB1CC1 | c.912del p.F304Lfs*6 | Frame Shift Del (DEL) | VAF 29/126 reads (23%) | called by mutect2, pindel, varscan2
- RBMS1 | c.1199A>G p.Y400C | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RGPD3 | c.2256G>T p.Q752H | Missense Mutation (SNP) | VAF 85/533 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- RHOT2 | c.124A>G p.I42V | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RHPN1 | c.1306C>A p.L436I | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- RIC8B | c.1295G>A p.C432Y | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- RIF1 | c.767_770del p.F256Sfs*21 | Frame Shift Del (DEL) | VAF 40/178 reads (22%) | called by pindel, varscan2
- RIMBP3 | c.1562A>G p.N521S | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.03); called by mutect2, varscan2
- RNF123 | c.3491C>A p.P1164Q | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF181 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- RNF40 | c.1850G>T p.R617L | Missense Mutation (SNP) | VAF 59/231 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ROBO3 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RPS6KA2 | c.892C>A p.P298T | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- RUFY3 | c.677_679del p.G226del | In Frame Del (DEL) | VAF 31/135 reads (23%) | called by mutect2, pindel, varscan2
- RUNDC1 | c.506A>G p.Q169R | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.97); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RYR3 | c.8251_8253dup p.K2751dup (on ENST00000389232; = p.K2752dup on NM_001036.6) | In Frame Ins (INS) | VAF 30/168 reads (18%) | called by mutect2, varscan2
- SBF1 | c.1984del p.V662* | Frame Shift Del (DEL) | VAF 27/250 reads (11%) | called by mutect2, pindel, varscan2
- SCAF1 | c.3540del p.T1181Pfs*28 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | called by mutect2, varscan2
- SCAF4 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 81/343 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SEC61A1 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 62/205 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SF3B3 | c.625_628del p.T209Sfs*4 | Frame Shift Del (DEL) | VAF 42/148 reads (28%) | called by pindel, varscan2
- SGK1 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 53/259 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SGPP1 | c.812T>C p.L271S | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SGPP2 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); called by muse, mutect2
- SGSM3 | c.1580-4A>G | Splice Region (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- SKOR2 | c.2510del p.P837Rfs*45 | Frame Shift Del (DEL) | VAF 37/163 reads (23%) | called by mutect2, pindel, varscan2
- SLC1A1 | c.1419G>T p.M473I | Missense Mutation (SNP) | VAF 65/246 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC26A8 | c.373A>G p.N125D | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC30A10 | c.383T>C p.V128A | Missense Mutation (SNP) | VAF 148/488 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- SLC5A8 | c.255del p.F85Lfs*35 | Frame Shift Del (DEL) | VAF 30/195 reads (15%) | called by mutect2, pindel, varscan2
- SLC7A1 | c.232G>T p.V78L | Missense Mutation (SNP) | VAF 115/405 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- SLC9A3R2 | c.214-1G>A p.X72_splice | Splice Site (SNP) | VAF 64/226 reads (28%) | called by mutect2, varscan2
- SLC9A4 | c.1264T>C p.C422R | Missense Mutation (SNP) | VAF 87/285 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SLITRK1 | c.1037G>A p.S346N | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- SMAD7 | c.482_483del p.K161Sfs*20 | Frame Shift Del (DEL) | VAF 18/186 reads (10%) | called by mutect2, pindel
- SMC1A | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 78/274 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- SNX19 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 36/309 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- SNX4 | c.597G>T p.K199N | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- SNX8 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SORBS1 | c.221G>T p.R74L (on ENST00000361941 / NM_001034954.2; = p.R42L on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- SP140L | c.796G>T p.G266C | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- SPAG17 | c.5736del p.F1912Lfs*5 | Frame Shift Del (DEL) | VAF 23/92 reads (25%) | called by mutect2, pindel, varscan2
- SPATA45 | c.54dup p.Q19Tfs*12 | Frame Shift Ins (INS) | VAF 35/160 reads (22%) | called by mutect2, pindel, varscan2
- SPEF1 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SPEG | c.5883del p.T1962Pfs*277 | Frame Shift Del (DEL) | VAF 19/92 reads (21%) | called by mutect2, pindel, varscan2
- SPEG | c.7019G>A p.S2340N | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SPTBN4 | c.4811C>T p.A1604V | Missense Mutation (SNP) | VAF 77/276 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SRCAP | c.6035C>A p.S2012Y | Missense Mutation (SNP) | VAF 113/385 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SSC5D | c.481dup p.R161Pfs*64 | Frame Shift Ins (INS) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- SSR3 | c.486del p.T163Qfs*2 | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | called by mutect2, pindel, varscan2
- STARD9 | c.5824del p.E1942Kfs*6 | Frame Shift Del (DEL) | VAF 52/269 reads (19%) | called by mutect2, pindel, varscan2
- STK31 | c.1602del p.F534Lfs*9 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- STRN4 | c.1115G>A p.G372D | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- SUPT16H | c.2294C>T p.A765V | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SYNDIG1 | c.163del p.A55Pfs*87 | Frame Shift Del (DEL) | VAF 82/334 reads (25%) | called by mutect2, pindel, varscan2
- SYNE2 | c.5961-1G>T p.X1987_splice | Splice Site (SNP) | VAF 54/234 reads (23%) | called by muse, mutect2, varscan2
- TAOK2 | c.275G>T p.R92L | Missense Mutation (SNP) | VAF 80/357 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- TBC1D10C | c.468G>A p.G156= | Splice Region (SNP) | VAF 76/279 reads (27%) | called by muse, mutect2, varscan2
- TBC1D23 | c.601-1G>A p.X201_splice | Splice Site (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- TEAD2 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 48/275 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TENM3 | c.6406G>T p.G2136* | Nonsense Mutation (SNP) | VAF 40/151 reads (26%) | called by muse, mutect2, varscan2
- TEX13C | c.1676C>A p.P559H | Missense Mutation (SNP) | VAF 161/556 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- TFE3 | c.1445del p.G482Dfs*44 | Frame Shift Del (DEL) | VAF 93/278 reads (33%) | called by mutect2, varscan2
- THBD | c.361A>G p.R121G | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- TIE1 | c.1589G>T p.G530V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TIMELESS | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 82/296 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- TINAGL1 | c.374+4_374+7del p.X125_splice | Splice Site (DEL) | VAF 15/96 reads (16%) | called by mutect2, pindel, varscan2
- TJP3 | c.2033T>C p.V678A | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- TKTL2 | c.487T>A p.S163T | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- TLR2 | c.103A>C p.I35L | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM140 | c.419A>G p.K140R | Missense Mutation (SNP) | VAF 57/242 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TMEM151B | c.893G>A p.C298Y | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- TMEM185B | c.1022del p.P341Lfs*4 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, varscan2
- TMEM26 | c.961G>T p.G321C | Missense Mutation (SNP) | VAF 60/253 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- TNNC1 | c.338A>G p.D113G | Missense Mutation (SNP) | VAF 76/270 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- TOP3A | c.2144+1G>A p.X715_splice | Splice Site (SNP) | VAF 24/92 reads (26%) | called by muse, mutect2, varscan2
- TRIM62 | c.54C>A p.Y18* | Nonsense Mutation (SNP) | VAF 66/312 reads (21%) | called by muse, mutect2
- TRIM62 | c.52T>C p.Y18H | Missense Mutation (SNP) | VAF 65/311 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRIM9 | c.1983del p.F661Lfs*10 | Frame Shift Del (DEL) | VAF 56/232 reads (24%) | called by mutect2, pindel, varscan2
- TRIO | c.2248del p.H750Tfs*64 | Frame Shift Del (DEL) | VAF 42/167 reads (25%) | called by mutect2, pindel, varscan2
- TRNAU1AP | c.487C>A p.L163M | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPC3 | c.809G>T p.G270V (on ENST00000379645 / NM_001366479.2; = p.G197V on NM_003305.2) | Missense Mutation (SNP) | VAF 12/332 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2
- TSC1 | c.2372A>T p.N791I | Missense Mutation (SNP) | VAF 78/288 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- TSHZ2 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.97214C>T p.A32405V (on ENST00000591111; = p.A24981V on NM_003319.4) | Missense Mutation (SNP) | VAF 33/158 reads (21%) | PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- TTN | c.40035del p.K13345Nfs*30 (on ENST00000591111; = p.K5921Nfs*30 on NM_003319.4) | Frame Shift Del (DEL) | VAF 18/141 reads (13%) | called by mutect2, pindel, varscan2
- TULP2 | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- UBN1 | c.1514G>T p.R505M | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- UBQLN2 | c.1574del p.P525Lfs*71 | Frame Shift Del (DEL) | VAF 50/214 reads (23%) | called by mutect2, pindel, varscan2
- UBTF | c.488A>G p.Q163R | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- UCKL1 | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ULK2 | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 21/212 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.193); called by muse, mutect2
- URAD | c.470T>C p.I157T | Missense Mutation (SNP) | VAF 117/382 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- URB1 | c.2703dup p.A902Sfs*68 | Frame Shift Ins (INS) | VAF 107/486 reads (22%) | called by mutect2, pindel, varscan2
- URGCP | c.1642del p.V548Cfs*13 (on ENST00000453200 / NM_001077663.3; = p.V539Cfs*13 on NM_017920.4) | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | called by mutect2, pindel, varscan2
- USF2 | c.132G>T p.E44D | Missense Mutation (SNP) | VAF 83/380 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USP43 | c.794del p.F265Sfs*16 | Frame Shift Del (DEL) | VAF 52/204 reads (25%) | called by mutect2, pindel, varscan2
- VPS13C | c.9094G>A p.D3032N (on ENST00000644861 / NM_020821.3; = p.D2989N on NM_017684.5) | Missense Mutation (SNP) | VAF 81/263 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- WBP1 | c.551del p.P184Lfs*11 | Frame Shift Del (DEL) | VAF 43/200 reads (22%) | called by pindel, varscan2
- WDFY3 | c.4726G>T p.G1576C | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- WDR13 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- WDR62 | c.2970G>T p.E990D | Missense Mutation (SNP) | VAF 143/508 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- WNK3 | c.4276dup p.C1426Lfs*2 | Frame Shift Ins (INS) | VAF 47/195 reads (24%) | called by mutect2, pindel, varscan2
- WNT4 | c.988T>A p.F330I | Missense Mutation (SNP) | VAF 51/280 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WSB2 | c.964C>A p.L322M | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- WSCD2 | c.1324C>T p.H442Y | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- ZBTB34 | c.664G>T p.G222* | Nonsense Mutation (SNP) | VAF 55/200 reads (28%) | called by muse, mutect2, varscan2
- ZCCHC7 | c.1068del p.G357Afs*38 | Frame Shift Del (DEL) | VAF 40/165 reads (24%) | called by mutect2, pindel, varscan2
- ZDHHC8 | c.422T>C p.I141T | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ZHX1 | c.70T>G p.L24V | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF148 | c.428dup p.K144Efs*16 | Frame Shift Ins (INS) | VAF 35/181 reads (19%) | called by mutect2, pindel, varscan2
- ZNF185 | c.224G>T p.R75M | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF331 | c.734G>A p.C245Y | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF454 | c.22A>G p.T8A | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF585B | c.2170G>T p.G724W | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF592 | c.2236C>T p.Q746* | Nonsense Mutation (SNP) | VAF 100/410 reads (24%) | called by muse, mutect2, varscan2
- ZNF628 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ABCA7 | c.2367G>A p.P789= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs926814950, COSV54034424; called by muse, mutect2, varscan2
- ADGRE3 | c.918C>T p.Y306= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs1230460812; called by muse, mutect2, varscan2
- AGAP3 | c.330C>G p.R110= (on ENST00000622464; = p.R146= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/108 reads (18%) | called by muse, mutect2, varscan2
- AJAP1 | c.1167C>A p.P389= | Silent (SNP) | VAF 32/199 reads (16%) | called by muse, mutect2, varscan2
- AL441992.2 | c.1125G>A p.T375= | Silent (SNP) | VAF 60/214 reads (28%) | catalogued as rs202219883; called by muse, mutect2, varscan2
- ANKLE1 | c.1470A>G p.P490= (on ENST00000394458; = p.P436= on NM_152363.6) | Silent (SNP) | VAF 59/271 reads (22%) | called by muse, mutect2, varscan2
- ANKRD11 | c.5820C>T p.S1940= | Silent (SNP) | VAF 46/215 reads (21%) | catalogued as rs368770538; called by muse, mutect2, varscan2
- AP1B1 | c.1365C>T p.Y455= | Silent (SNP) | VAF 85/294 reads (29%) | catalogued as rs375188354; called by muse, mutect2, varscan2
- ARAF | c.624G>A p.Q208= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV51693829; called by muse, varscan2
- ATP1B3 | c.306G>A p.S102= | Silent (SNP) | VAF 42/138 reads (30%) | catalogued as rs777316470; called by muse, mutect2, varscan2
- AVP | c.414G>A p.P138= | Silent (SNP) | VAF 40/129 reads (31%) | catalogued as rs1223764468; called by muse, mutect2, varscan2
- B3GNT3 | c.366C>T p.R122= | Silent (SNP) | VAF 27/125 reads (22%) | catalogued as COSV100592786; called by muse, mutect2, varscan2
- BCL11B | c.1443C>T p.A481= (on ENST00000357195 / NM_001282237.2; = p.A410= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 122/397 reads (31%) | catalogued as rs932315850, COSV61734471; called by muse, mutect2, varscan2
- BRCA2 | c.5712T>C p.L1904= | Silent (SNP) | VAF 29/118 reads (25%) | called by muse, mutect2, varscan2
- C16orf96 | c.1953C>T p.S651= | Silent (SNP) | VAF 85/282 reads (30%) | called by muse, mutect2, varscan2
- C1orf185 | c.459C>T p.D153= | Silent (SNP) | VAF 48/203 reads (24%) | catalogued as COSV65624875; called by muse, mutect2, varscan2
- CADM3 | c.813C>T p.G271= (on ENST00000368125 / NM_001127173.3; = p.G305= on NM_021189.5) | Silent (SNP) | VAF 41/148 reads (28%) | catalogued as rs780970214; called by muse, mutect2, varscan2
- CANX | c.1080T>C p.C360= | Silent (SNP) | VAF 71/247 reads (29%) | called by muse, mutect2, varscan2
- CCNY | c.957C>T p.S319= | Silent (SNP) | VAF 49/218 reads (22%) | catalogued as rs766833961; called by muse, mutect2, varscan2
- CDK2 | c.735G>A p.R245= | Silent (SNP) | VAF 57/431 reads (13%) | called by muse, mutect2, varscan2
- CELSR1 | c.5283C>T p.S1761= | Silent (SNP) | VAF 63/179 reads (35%) | catalogued as rs141170525; called by muse, mutect2, varscan2
- CFAP206 | c.666C>T p.T222= | Silent (SNP) | VAF 63/273 reads (23%) | catalogued as rs1264738922, COSV99739943; called by muse, mutect2, varscan2
- CILP2 | c.2232C>T p.Y744= | Silent (SNP) | VAF 54/200 reads (27%) | catalogued as rs1406277815, COSV99365134; called by muse, mutect2, varscan2
- COL26A1 | c.648C>T p.P216= (on ENST00000313669 / NM_001278563.3; = p.P214= on NM_133457.4) | Silent (SNP) | VAF 50/197 reads (25%) | catalogued as rs149289538, COSV58123906; called by muse, mutect2, varscan2
- CPTP | c.213G>A p.P71= | Silent (SNP) | VAF 64/219 reads (29%) | catalogued as rs754553906; called by muse, mutect2, varscan2
- CREB3L2 | c.1164C>A p.A388= | Silent (SNP) | VAF 45/182 reads (25%) | catalogued as COSV100382005, COSV104398395; called by muse, mutect2, varscan2
- CUL9 | c.7473C>A p.S2491= | Silent (SNP) | VAF 49/199 reads (25%) | called by mutect2, varscan2
- CYP2A6 | c.867A>G p.K289= | Silent (SNP) | VAF 76/284 reads (27%) | catalogued as rs2644905; called by mutect2, varscan2
- CYTH3 | c.576G>A p.V192= | Silent (SNP) | VAF 42/146 reads (29%) | called by muse, mutect2, varscan2
- DCHS1 | c.5832G>A p.V1944= | Silent (SNP) | VAF 51/199 reads (26%) | called by muse, mutect2, varscan2
- DDX20 | c.342T>C p.C114= | Silent (SNP) | VAF 16/179 reads (9%) | catalogued as rs1438288121; called by muse, mutect2
- DDX47 | c.567C>T p.D189= | Silent (SNP) | VAF 26/126 reads (21%) | called by muse, mutect2, varscan2
- DIP2A | c.609C>T p.A203= | Silent (SNP) | VAF 34/99 reads (34%) | catalogued as rs978031751; called by muse, mutect2, varscan2
- DKK1 | c.399C>T p.C133= | Silent (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- DMAC2 | c.459G>A p.L153= | Silent (SNP) | VAF 32/143 reads (22%) | catalogued as rs782522516; called by muse, mutect2, varscan2
- DMD | c.8086C>T p.L2696= | Silent (SNP) | VAF 95/373 reads (25%) | catalogued as CD961958; called by muse, mutect2, varscan2
- DNMT1 | c.897C>T p.P299= | Silent (SNP) | VAF 88/348 reads (25%) | catalogued as rs373861581; called by muse, varscan2
319 further variants in this file (0 protein-altering or splice-affecting, 154 silent, 165 other) are not listed here.
